Gene-level copy-number profile of tumor specimen TCGA-HT-A61B-01A from TCGA case TCGA-HT-A61B, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 22.8 years (8,335 days).
Specimen TCGA-HT-A61B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.3b8335e5-420c-495f-9c07-d96ea4b9b48e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-A61B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c29896d-2e20-4420-bcd4-4041109a5dba

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 92; copy number 2: 4,483; copy number 3: 12,949; copy number 4: 39,507; copy number 5: 1,132; copy number 6: 1,523; copy number 10: 4; copy number 11: 10; copy number 13: 4; copy number 14: 6; copy number 19: 9; copy number 21: 5; copy number 22: 7; copy number 24: 6; copy number 25: 1; copy number 29: 46; copy number 30: 5; copy number 33: 6; copy number 37: 11; copy number 43: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-HT-A61B-01): tumor purity 0.76, ploidy 3.69, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 121 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:899,462–1,367,613, 6 genes, copy number 33 (within-gene range 3–33): LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2.
- chr2:9,757,496–9,770,341, 1 gene, copy number 25 (within-gene range 3–25): AC082651.3.
- chr2:10,302,889–10,457,693, 4 genes, copy number 10 (within-gene range 3–10): HPCAL1, ODC1, SNORA80B, ODC1-DT.
- chr2:12,780,593–13,609,168, 3 genes, copy number 13 (within-gene range 3–13): AC064875.1, AC093912.1, AC073062.1.
- chr2:13,723,048–13,758,152, 1 gene, copy number 13: AC016730.1.
- chr2:15,801,747–16,105,841, 11 genes, copy number 37: AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1.
- chr2:56,750,300–56,750,563, 1 gene, copy number 43: PPIAP63.
- chr2:69,013,179–69,249,327, 1 gene, copy number 11 (within-gene range 3–30): ANTXR1.
- chr2:69,103,682–69,387,250, 6 genes, copy number 11–30 (within-gene range 3–30): MIR3126, RNA5SP96, RNU6-1216P, AC112230.1, GFPT1, Y_RNA.
- chr2:75,455,994–75,628,168, 7 genes, copy number 29: GAPDHP57, EVA1A, AC007099.2, AC007099.3, AC007099.1, AC005034.1, U3.
- chr2:104,580,821–105,145,424, 19 genes, copy number 29: AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114, HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918.
- chr5:1,173,141–1,309,377, 6 genes, copy number 14: CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457.
- chr5:6,289,857–6,533,200, 6 genes, copy number 11: HMGB3P3, LINC02145, MED10, AC093307.1, UBE2QL1, AC027334.1.
- chr5:7,226,156–7,345,921, 7 genes, copy number 22: AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3.
- chr5:8,793,875–8,898,052, 2 genes, copy number 30 (within-gene range 4–30): AC091932.3, LINC02199.
- chr11:55,635,113–55,881,243, 20 genes, copy number 19–24 (within-gene range 3–24): OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2, OR5D16, OR9M1P, AC036111.2, AC036111.3, AC036111.1.
- chr11:55,993,681–56,215,222, 20 genes, copy number 29: OR5F1, OR5F2P, OR5AS1, OR5AQ1P, OR5J1P, OR5BE1P, OR8I2, OR8I4P, OR8H2, OR5BN2P, OR8H3, OR5BN1P, OR8J3, OR8K4P, OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2.

Autosomal genes at a single copy (total copy number 1): 92. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
